Surgical pathology report (de-identified scan), TCGA case TCGA-75-5122, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Ontario Institute for Cancer Research (OICR), specimen TCGA-75-5122-01A (Primary Tumor).

75-5722

Description for each data link can be found in the Data description worksheet (yellow tab).

Sample Collection Details

Histology and staging

Sample Number	Sample Type	Sample Preparation	Site of Tissue	Diagnosis	Year of Sample Collection	Age at Sample Collection (yrs)	Sample Comments	Days to Procedure Date	Days to Diagnosis	Type of Procedure	Site of Primary (Histology)	Tumour Size (cm)	Histology	Grade/ Differentiation	Pathological T	Pathological N	Clinical M	VALSG Stage	Histology Comments	Slide Image
	TUMOUR	FF		Adenocarcinoma				0	13	RESECT	LUL	4.00	03	III	T2,N0S	N0	M0			
	BUFFY	FF		Adenocarcinoma				5	8	RESECT	LUL	4.00	03	III	T2,N0S	N0	M0			

Source: NCI Genomic Data Commons file 73d7a3cf-46eb-43c1-9729-fc0b4a2d03eb (TCGA-75-5122.A664B87C-A7EF-4F18-9E4D-D37D0CCAAF70.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).